Surgical pathology report (de-identified scan), TCGA case TCGA-HR-A5NC, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HR-A5NC-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	Cutaneous malignant melanoma
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	Resection
Site of Tissue/Primary (Histology)	Trunk including anal margin and perianal skin
Tumour Size (cm)	20
Histology	Cutaneous malignant melanoma
Grade/Differentiation	X
Pathological T	T4a
Pathological N	NX
Clinical M	MX
Histology Comments	Clark level - V

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD0-3

Melanoma, malignant 8720/3
Site Skin, anal, perianal C44.5
QW2/11/13

Criteria	W 2/7/13	Yes	No

Source: NCI Genomic Data Commons file db37b137-5b58-4519-b54c-dbd2dcee1a3c (TCGA-HR-A5NC.B8892054-09BB-4E2F-90FC-E84EBA310C7D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).